Somatic mutation profile of tumor specimen TCGA-KK-A8IA-01A (aliquot TCGA-KK-A8IA-01A-11D-A364-08) from TCGA case TCGA-KK-A8IA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 69.2 years (25,284 days).
Specimen TCGA-KK-A8IA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86e0c746-ea7b-4ec4-aa36-1563f424b634.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A8IA-11A (Solid Tissue Normal), aliquot TCGA-KK-A8IA-11A-11D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e82dbe02-b8be-41d5-99b0-b2e8b486f82b

The open-access MAF lists 34 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Frame Shift Ins 2, Frame Shift Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACP1 | c.54T>G p.C18W | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55242669, COSV99681622; called by muse, mutect2, varscan2
- AFG3L2 | c.2095G>A p.D699N | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV52313137; called by muse, varscan2
- CPM | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV100615098; called by muse, mutect2, varscan2
- CTNND2 | c.2801T>G p.M934R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV58877431; called by muse, mutect2, varscan2
- ECI2 | c.313G>T p.E105* (on ENST00000380118 / NM_206836.3; = p.E75* on NM_006117.2) | Nonsense Mutation (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100326494; called by muse, mutect2, varscan2
- FCRL6 | c.522C>A p.D174E | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs774198604, COSV100220204; called by muse, mutect2, varscan2
- FILIP1 | c.2308C>T p.L770F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV99384965; called by muse, mutect2, varscan2
- FNDC1 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); catalogued as rs1190667940, COSV51931872; called by muse, mutect2, varscan2
- LIMK1 | c.741C>G p.S247R | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100283205; called by muse, mutect2, varscan2
- LONRF1 | c.745A>C p.I249L | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV101238223; called by muse, mutect2, varscan2
- LTBP2 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.701); catalogued as rs760735135, COSV100000386, COSV100001139; called by muse, mutect2, varscan2
- MAGEA4 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1225342823, COSV52341486; called by muse, mutect2
- MS4A2 | c.390C>G p.S130R | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as COSV99627311; called by muse, mutect2, varscan2
- NAA15 | c.571G>A p.E191K | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV99649606; called by muse, mutect2, varscan2
- NLRC5 | c.4175A>G p.D1392G | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1312334726, COSV99347413; called by muse, mutect2, varscan2
- OR6K2 | c.943G>A p.V315I | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs141972386, COSV62743235; called by muse, mutect2, varscan2
- PNKP | c.928G>C p.D310H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749118287, COSV99681791; called by muse, mutect2, varscan2
- POM121L12 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.573); catalogued as rs565383229, COSV68693234; called by muse, mutect2, varscan2
- RAC3 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100141833; called by muse, mutect2, varscan2
- SHANK1 | c.6442C>T p.R2148C | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99521318; called by muse, mutect2, varscan2
- WTAP | c.485G>C p.R162P | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV61610446, COSV61610540; called by muse, mutect2, varscan2
- ZNF831 | c.973A>G p.K325E | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.352); catalogued as rs1171949249, COSV100926054; called by muse, mutect2, varscan2
- EIF4G1 | c.4031dup p.T1345Nfs*46 (on ENST00000346169 / NM_198241.3; = p.T1150Nfs*46 on NM_004953.5) | Frame Shift Ins (INS) | VAF 42/121 reads (35%) | called by mutect2, pindel, varscan2
- FOXA1 | c.1380_1407del p.Y460* | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- IGKV3-20 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- ZIC4 | c.809dup p.C271Lfs*13 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- CACNA1D | c.4260C>T p.L1420= (on ENST00000350061 / NM_001128840.3; = p.L1440= on NM_000720.4) | Silent (SNP) | VAF 54/135 reads (40%) | catalogued as COSV55466662, COSV99858326; called by muse, mutect2, varscan2
- SRRM4 | c.873G>A p.T291= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as rs367777055, COSV57410251; called by muse, mutect2, varscan2
- SYNE1 | c.8169C>T p.H2723= (on ENST00000367255 / NM_182961.4; = p.H2730= on NM_033071.3) | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as rs371449580; called by muse, mutect2, varscan2
- TTC21A | c.2658A>G p.Q886= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV100087343; called by muse, mutect2, varscan2
- VPS16 | c.1092C>T p.D364= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs757959009, COSV100988341; called by muse, mutect2, varscan2
- ZIC1 | c.336G>A p.A112= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs763182380, COSV99291969; called by muse, mutect2, varscan2
- DCHS2 | n.1918C>T | RNA (SNP) | VAF 31/72 reads (43%) | catalogued as rs1427915046, COSV59729765; called by muse, mutect2, varscan2
